MMRF case MMRF_2581 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1cdf1435-6fea-4fee-9d8a-35a7afdf51ac

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Dead; Days to death: 360 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.6 years (26,534 days); ISS stage: II; Days to last known disease status: 360 days; Days to last follow up: 360 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 83 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 360.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 3): M Protein 0.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 74.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 6.96 g/L; Immunoglobulin A 16 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 4.02 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 27 g/L; Total Protein 6.1 g/dL; Glucose 7.26 mmol/L; C-Reactive Protein 0.6 mg/dL.
- Day 83 (ECOG 3): Hemoglobin 7.13 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.5 mmol/L; Albumin 24 g/L; Total Protein 5.6 g/dL; Glucose 4.46 mmol/L.

Other clinical attributes
- Day 1: Weight: 53 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_2581_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2581_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
